Somatic mutation profile of tumor specimen MMRF_1595_1_BM_CD138pos (aliquot MMRF_1595_1_BM_CD138pos_T1_KBS5U_L03484) from MMRF case MMRF_1595, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Dead; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 73.8 years (26,950 days).
Specimen MMRF_1595_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2bd3b988-5411-47c9-a372-1f3838860c19.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1595_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1595_1_PB_Whole_C2_KBS5U_L03496; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ed585ef9-690d-4126-aa25-a5d440f1a676

The open-access MAF lists 179 somatic variants for this specimen: 78 protein-altering or splice-affecting, 9 silent, 92 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 67, 3'UTR 53, Intron 23, Silent 9, 5'UTR 6, Frame Shift Del 4, RNA 4, Nonsense Mutation 4, 3'Flank 3, 5'Flank 3, Splice Site 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP2B2 | c.2920G>A p.A974T (on ENST00000352432; = p.A940T on NM_001683.5) | Missense Mutation (SNP) | VAF 52/136 reads (38%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.572); catalogued as rs146069247; called by muse, mutect2, varscan2
- BMP2 | c.329G>A p.R110H | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV101122107; called by muse, mutect2, varscan2
- C19orf81 | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1400581788; called by muse, mutect2, varscan2
- C8orf34 | c.766del p.X256_splice | Splice Site (DEL) | VAF 37/97 reads (38%) | catalogued as COSV61381987; called by mutect2, pindel, varscan2
- CEP250 | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 27/57 reads (47%) | SIFT tolerated (0.13); PolyPhen benign (0.012); catalogued as COSV100699228, COSV61171245; called by muse, mutect2, varscan2
- CREG2 | c.777G>C p.K259N | Missense Mutation (SNP) | VAF 21/268 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61316663; called by muse, mutect2
- CYP2A7 | c.770G>A p.R257H | Missense Mutation (SNP) | VAF 39/84 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs758994683, COSV99393600; called by muse, mutect2, varscan2
- DDX17 | c.130_152del p.P44Ifs*42 | Frame Shift Del (DEL) | VAF 18/70 reads (26%) | catalogued as rs1569145138; called by mutect2, varscan2
- FAT3 | c.6116G>A p.G2039E | Missense Mutation (SNP) | VAF 38/104 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53169834; called by muse, mutect2, varscan2
- IGKV4-1 | c.182G>A p.W61* | Nonsense Mutation (SNP) | VAF 56/65 reads (86%) | catalogued as rs778196241; called by muse, varscan2
- IGKV4-1 | c.183G>A p.W61* | Nonsense Mutation (SNP) | VAF 56/64 reads (88%) | catalogued as rs151106836; called by muse, varscan2
- KCTD7 | c.335G>C p.R112P | Missense Mutation (SNP) | VAF 15/205 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51877044, COSV99299062; called by muse, mutect2
- KMT2C | c.868C>A p.H290N | Missense Mutation (SNP) | VAF 8/177 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV51481375; called by muse, mutect2
- LCT | c.490G>T p.D164Y | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs902517772; called by muse, mutect2, varscan2
- LRRTM1 | c.217C>T p.R73C | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV54446803; called by muse, mutect2, varscan2
- MAX | c.104G>T p.R35L | Missense Mutation (SNP) | VAF 20/28 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV52416276, COSV52416985, COSV52418829; called by muse, mutect2, varscan2
- NES | c.4586G>A p.G1529E | Missense Mutation (SNP) | VAF 104/241 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.014); catalogued as COSV100957840; called by muse, mutect2, varscan2
- NLRP13 | c.1572G>C p.K524N | Missense Mutation (SNP) | VAF 37/51 reads (73%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as COSV100738627, COSV61620108, COSV61620646; called by muse, mutect2, varscan2
- PEX2 | c.573G>T p.M191I | Missense Mutation (SNP) | VAF 74/178 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.457); catalogued as COSV63813759; called by muse, mutect2, varscan2
- PUM1 | c.1447G>A p.A483T | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.01); catalogued as rs761527078; called by muse, varscan2
- SLC1A4 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 3/9 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.425); catalogued as rs1252242158; called by muse, mutect2
- SMAD1 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 71/149 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1260108423; called by muse, mutect2, varscan2
- SMCHD1 | c.2561C>T p.T854I | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs766086191; called by muse, mutect2, varscan2
- SNX7 | c.710C>T p.A237V | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as rs756173460; called by muse, mutect2, varscan2
- TBATA | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 57/144 reads (40%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs776723435, COSV100165508; called by muse, mutect2, varscan2
- TENM3 | c.3400G>A p.G1134R | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs369585956, COSV101305380; called by muse, mutect2, varscan2
- TKTL1 | c.718A>T p.R240* | Nonsense Mutation (SNP) | VAF 70/83 reads (84%) | catalogued as COSV54214195; called by muse, mutect2, varscan2
- TRAM1L1 | c.1027A>T p.K343* | Nonsense Mutation (SNP) | VAF 150/307 reads (49%) | catalogued as COSV60291158; called by muse, mutect2, varscan2
- TRMT9B | c.625T>C p.S209P | Missense Mutation (SNP) | VAF 35/52 reads (67%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.896); catalogued as rs759934606; called by muse, mutect2, varscan2
- USH2A | c.9507G>T p.K3169N | Missense Mutation (SNP) | VAF 85/187 reads (45%) | SIFT tolerated (0.46); PolyPhen benign (0.203); catalogued as COSV100233830; called by muse, mutect2, varscan2
- ZNF648 | c.1177C>T p.R393C | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.02); catalogued as COSV60570281; called by muse, mutect2, varscan2
- ZNF648 | c.553G>C p.G185R | Missense Mutation (SNP) | VAF 71/174 reads (41%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs1262684484, COSV60569515; called by muse, mutect2, varscan2
- ACVR1B | c.1040G>A p.G347D | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- ADARB2 | c.1697G>T p.G566V | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP8B1 | c.2974T>C p.Y992H | Missense Mutation (SNP) | VAF 21/49 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CHIC1 | c.565C>A p.L189I | Missense Mutation (SNP) | VAF 25/26 reads (96%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CLASP2 | c.1247T>A p.L416H | Missense Mutation (SNP) | VAF 40/210 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2, varscan2
- COLEC12 | c.1147A>T p.T383S | Missense Mutation (SNP) | VAF 98/221 reads (44%) | SIFT tolerated (0.32); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- CPS1 | c.1508G>A p.G503E | Missense Mutation (SNP) | VAF 27/78 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DCDC1 | c.4880T>C p.I1627T (on ENST00000597505 / NM_001367979.1; = p.I734T on NM_020869.3) | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.509); called by muse, mutect2, varscan2
- DELE1 | c.835G>T p.A279S | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DKKL1 | c.627C>G p.H209Q | Missense Mutation (SNP) | VAF 77/157 reads (49%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- DNAH12 | c.8522A>T p.Y2841F (on ENST00000351747; = p.Y3709F on NM_001366028.2) | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- DSCAML1 | c.6241G>T p.G2081W (on ENST00000321322; = p.G2021W on NM_020693.4) | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- F13B | c.1129A>T p.T377S | Missense Mutation (SNP) | VAF 79/162 reads (49%) | SIFT tolerated (0.4); PolyPhen benign (0.253); called by mutect2, varscan2
- FLCN | c.1555_1591del p.F519Tfs*6 | Frame Shift Del (DEL) | VAF 44/62 reads (71%) | called by mutect2, pindel
- FMO4 | c.410G>C p.R137T | Missense Mutation (SNP) | VAF 90/219 reads (41%) | SIFT tolerated (0.42); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GAD1 | c.863_867del p.Q289Sfs*16 | Frame Shift Del (DEL) | VAF 30/66 reads (45%) | called by mutect2, pindel, varscan2
- HTRA1 | c.1160T>A p.M387K | Missense Mutation (SNP) | VAF 46/106 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- INPP4B | c.995A>T p.K332I | Missense Mutation (SNP) | VAF 56/91 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIAA1549 | c.4930-2A>T p.X1644_splice | Splice Site (SNP) | VAF 62/139 reads (45%) | called by muse, mutect2, varscan2
- LRRTM1 | c.1542G>T p.Q514H | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.993); called by muse, mutect2
- MACF1 | c.15734_15735del p.L5245Qfs*2 (on ENST00000372915; = p.L3178Qfs*2 on NM_012090.5) | Frame Shift Del (DEL) | VAF 66/170 reads (39%) | called by mutect2, pindel, varscan2
- NFATC2 | c.1614G>C p.K538N | Missense Mutation (SNP) | VAF 90/165 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NUP107 | c.1738T>G p.L580V | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); called by muse, mutect2, varscan2
- PASK | c.3541G>A p.G1181R | Missense Mutation (SNP) | VAF 4/62 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCARE | c.77A>C p.K26T | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- PHB2 | c.794C>T p.A265V | Missense Mutation (SNP) | VAF 91/196 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- PRAMEF19 | c.910T>C p.S304P | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.248); called by muse, mutect2, varscan2
- RASIP1 | c.536C>T p.A179V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.977); called by muse, mutect2
- RNF19A | c.2329A>C p.I777L | Missense Mutation (SNP) | VAF 78/199 reads (39%) | SIFT tolerated, low confidence (0.81); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF222 | c.244G>T p.D82Y | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC17A8 | c.1615T>A p.F539I | Missense Mutation (SNP) | VAF 41/154 reads (27%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC35F1 | c.1086G>T p.Q362H | Missense Mutation (SNP) | VAF 18/226 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); called by muse, mutect2
- SLC7A13 | c.1303T>G p.F435V | Missense Mutation (SNP) | VAF 145/363 reads (40%) | SIFT tolerated (0.42); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- SPIDR | c.2305T>A p.S769T | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- SS18 | c.435G>A p.M145I | Missense Mutation (SNP) | VAF 60/137 reads (44%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- TECPR2 | c.923G>C p.S308T | Missense Mutation (SNP) | VAF 27/37 reads (73%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TEX13C | c.2972A>G p.D991G | Missense Mutation (SNP) | VAF 32/39 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- TEX36 | c.175dup p.R59Pfs*8 | Frame Shift Ins (INS) | VAF 28/92 reads (30%) | called by mutect2, pindel, varscan2
- TJP1 | c.3770C>T p.P1257L | Missense Mutation (SNP) | VAF 61/141 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- TTC34 | c.1763T>C p.V588A | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.462); called by muse, mutect2
- VSIG10 | c.1492G>C p.D498H | Missense Mutation (SNP) | VAF 69/164 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- WDFY3 | c.6031G>A p.D2011N | Missense Mutation (SNP) | VAF 18/61 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- WDFY3 | c.3728G>C p.S1243T | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT tolerated (0.33); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- ZC3H6 | c.805A>G p.T269A | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ZNF521 | c.3743G>A p.S1248N | Missense Mutation (SNP) | VAF 35/69 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- ZNF608 | c.4348G>A p.D1450N | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- CYP4F12 | c.409C>T p.L137= | Silent (SNP) | VAF 46/102 reads (45%) | catalogued as rs761590121; called by muse, mutect2, varscan2
- DOCK7 | c.4152G>A p.L1384= (on ENST00000635253 / NM_001367561.1; = p.L1353= on NM_033407.3) | Silent (SNP) | VAF 31/77 reads (40%) | called by muse, mutect2, varscan2
- FZD5 | c.1458C>T p.C486= | Silent (SNP) | VAF 65/115 reads (57%) | called by muse, mutect2, varscan2
- GJD2 | c.597C>T p.Y199= | Silent (SNP) | VAF 40/106 reads (38%) | called by muse, mutect2, varscan2
- GOLPH3L | c.804G>A p.K268= | Silent (SNP) | VAF 29/143 reads (20%) | called by muse, mutect2, varscan2
- OR2T27 | c.159C>T p.S53= | Silent (SNP) | VAF 16/84 reads (19%) | catalogued as COSV100788280; called by muse, mutect2, varscan2
- SH3BP2 | c.435C>T p.S145= | Silent (SNP) | VAF 9/142 reads (6%) | called by muse, mutect2
- ZNF467 | c.1761G>A p.E587= | Silent (SNP) | VAF 7/97 reads (7%) | catalogued as rs1480732447; called by muse, mutect2
- ZNF839 | c.732G>A p.T244= (on ENST00000558850 / NM_001267827.1; = p.T360= on NM_018335.5) | Silent (SNP) | VAF 13/19 reads (68%) | catalogued as rs375280717; called by muse, mutect2, varscan2
- AC103993.1 | n.1190A>T | RNA (SNP) | VAF 60/139 reads (43%) | called by muse, mutect2, varscan2
- AC244517.10 | c.36-9762C>G | Intron (SNP) | VAF 4/68 reads (6%) | catalogued as COSV101595538; called by muse, mutect2
- ADAM6 | n.640G>T | RNA (SNP) | VAF 50/70 reads (71%) | called by muse, mutect2, varscan2
- ADARB1 | c.*976G>C | 3'UTR (SNP) | VAF 3/44 reads (7%) | catalogued as rs1396235054; called by muse, mutect2
- ADCYAP1 | c.*82C>G | 3'UTR (SNP) | VAF 9/171 reads (5%) | called by muse, mutect2
- ADO | c.*1437A>T | 3'UTR (SNP) | VAF 36/91 reads (40%) | called by muse, mutect2, varscan2
- AL390066.1 | n.571A>T | RNA (SNP) | VAF 10/136 reads (7%) | called by muse, mutect2
- ALPP | c.*482del | 3'UTR (DEL) | VAF 58/153 reads (38%) | catalogued as rs1189844049; called by mutect2, pindel, varscan2
- ANK1 | c.*487C>T | 3'UTR (SNP) | VAF 3/41 reads (7%) | catalogued as COSV55886231; called by muse, mutect2
- ANO1 | c.1951-55G>A | Intron (SNP) | VAF 11/20 reads (55%) | called by muse, mutect2
- APLP2 | c.2034+46T>C | Intron (SNP) | VAF 4/45 reads (9%) | called by muse, mutect2
- ARSD | c.1000+940A>T | Intron (SNP) | VAF 49/61 reads (80%) | called by muse, mutect2, varscan2
- B3GALNT1 | c.-221+104G>A | Intron (SNP) | VAF 10/200 reads (5%) | called by muse, mutect2
- B4GALT6 | c.*2417A>T | 3'UTR (SNP) | VAF 24/63 reads (38%) | called by muse, mutect2, varscan2
- BPNT2 | c.*5214A>G | 3'UTR (SNP) | VAF 4/65 reads (6%) | catalogued as rs1164832310; called by muse, mutect2
- CALU | c.-11-230G>T | Intron (SNP) | VAF 115/291 reads (40%) | called by muse, mutect2, varscan2
- CCDC18 | chr1:93278730 del A | 3'Flank (DEL) | VAF 28/68 reads (41%) | called by mutect2, pindel, varscan2
- CCSAP | c.*3239T>G | 3'UTR (SNP) | VAF 22/38 reads (58%) | called by muse, mutect2, varscan2
- CDC42SE1 | c.-58A>G | 5'UTR (SNP) | VAF 83/201 reads (41%) | called by muse, mutect2, varscan2
- CDH11 | c.811+60T>C | Intron (SNP) | VAF 19/23 reads (83%) | called by muse, varscan2
- CDON | c.*3943C>A | 3'UTR (SNP) | VAF 6/100 reads (6%) | called by muse, mutect2
- CELSR1 | c.9036-91C>A | Intron (SNP) | VAF 11/59 reads (19%) | called by muse, mutect2, varscan2
- COL12A1 | c.*979G>T | 3'UTR (SNP) | VAF 21/41 reads (51%) | catalogued as rs1373555191; called by muse, mutect2, varscan2
- CRP | c.*248G>A | 3'UTR (SNP) | VAF 37/80 reads (46%) | called by muse, mutect2, varscan2
- CSMD3 | c.*440G>A | 3'UTR (SNP) | VAF 41/96 reads (43%) | catalogued as rs956887198, COSV99831086; called by muse, mutect2, varscan2
- CTSE | c.*596A>G | 3'UTR (SNP) | VAF 59/138 reads (43%) | called by muse, mutect2, varscan2
- CWC15 | c.245-45G>A | Intron (SNP) | VAF 12/79 reads (15%) | called by muse, mutect2
- DCN | c.211+3195A>T | Intron (SNP) | VAF 41/87 reads (47%) | called by muse, mutect2, varscan2
- DMRT1 | c.*150T>C | 3'UTR (SNP) | VAF 7/80 reads (9%) | called by muse, mutect2
- DNAI4 | c.643+108T>G | Intron (SNP) | VAF 21/40 reads (53%) | called by muse, mutect2, varscan2
- DNAJB9 | c.*1210A>G | 3'UTR (SNP) | VAF 50/128 reads (39%) | called by muse, mutect2, varscan2
- E2F1 | c.*1055C>T | 3'UTR (SNP) | VAF 36/76 reads (47%) | catalogued as rs1021433012; called by muse, mutect2, varscan2
- EGR3 | c.*1386T>C | 3'UTR (SNP) | VAF 10/12 reads (83%) | catalogued as rs778248690; called by muse, mutect2, varscan2
- EIF1B | c.-140C>A | 5'UTR (SNP) | VAF 41/194 reads (21%) | called by muse, mutect2, varscan2
- FAM3C | c.*217A>G | 3'UTR (SNP) | VAF 44/69 reads (64%) | called by mutect2, varscan2
- FKTN | c.*3755del | 3'UTR (DEL) | VAF 42/246 reads (17%) | called by mutect2, pindel, varscan2
- FNBP1L | c.*7T>C | 3'UTR (SNP) | VAF 111/255 reads (44%) | called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.2114+1876A>T | Intron (SNP) | VAF 30/87 reads (34%) | called by muse, mutect2, varscan2
- GABRB2 | c.*5316A>C | 3'UTR (SNP) | VAF 40/109 reads (37%) | called by muse, mutect2, varscan2
- GCNT4 | c.*549C>T | 3'UTR (SNP) | VAF 35/91 reads (38%) | called by muse, mutect2, varscan2
- GHR | c.136+18645C>A | Intron (SNP) | VAF 8/40 reads (20%) | catalogued as rs1561195237; called by muse, mutect2
- GPN1 | c.*72A>G | 3'UTR (SNP) | VAF 66/145 reads (46%) | called by muse, mutect2, varscan2
- GPR171 | c.*60C>G | 3'UTR (SNP) | VAF 10/18 reads (56%) | called by muse, mutect2, varscan2
- HOXA1 | c.*390C>G | 3'UTR (SNP) | VAF 13/134 reads (10%) | called by muse, mutect2
- IGKV1D-33 | c.-2G>A | 5'UTR (SNP) | VAF 4/18 reads (22%) | called by mutect2, varscan2
- KPNA5 | c.*45+1983G>A | Intron (SNP) | VAF 6/82 reads (7%) | catalogued as rs1354588815; called by muse, mutect2
- LNPEP | c.-26C>T | 5'UTR (SNP) | VAF 8/14 reads (57%) | called by muse, mutect2, varscan2
- LRFN2 | c.*67G>T | 3'UTR (SNP) | VAF 22/50 reads (44%) | called by muse, mutect2, varscan2
- MAP3K13 | c.1278+138T>C | Intron (SNP) | VAF 11/15 reads (73%) | called by muse, mutect2, varscan2
- MT1G | c.*123A>G | 3'UTR (SNP) | VAF 75/106 reads (71%) | called by muse, mutect2, varscan2
- MVB12B | c.*3044G>A | 3'UTR (SNP) | VAF 26/189 reads (14%) | catalogued as rs942298893; called by muse, mutect2, varscan2
- NAV2 | chr11:20119194 T>C | 3'Flank (SNP) | VAF 56/108 reads (52%) | catalogued as COSV60656441; called by muse, mutect2, varscan2
- NEGR1 | c.*4226T>C | 3'UTR (SNP) | VAF 28/61 reads (46%) | called by muse, mutect2, varscan2
- NFATC2IP | c.*661T>A | 3'UTR (SNP) | VAF 14/124 reads (11%) | called by muse, mutect2, varscan2
- OLIG2 | c.*980T>G | 3'UTR (SNP) | VAF 53/113 reads (47%) | called by muse, mutect2, varscan2
- OR2T2 | chr1:248441338 C>T | 5'Flank (SNP) | VAF 46/167 reads (28%) | called by muse, mutect2, varscan2
- PAX5 | c.*6700A>G | 3'UTR (SNP) | VAF 57/134 reads (43%) | catalogued as rs1414527318; called by muse, mutect2, varscan2
- PDLIM2 | chr8:22597067 C>A | 3'Flank (SNP) | VAF 6/31 reads (19%) | called by muse, mutect2, varscan2
- PFKL | c.*354C>T | 3'UTR (SNP) | VAF 41/69 reads (59%) | catalogued as rs952509131; called by muse, mutect2, varscan2
- PFKP | c.265-404G>A | Intron (SNP) | VAF 25/54 reads (46%) | catalogued as COSV66897977; called by muse, mutect2, varscan2
- PHC1P1 | n.723C>A | RNA (SNP) | VAF 37/96 reads (39%) | called by muse, mutect2, varscan2
- PPP1R7 | chr2:241150258 G>C | 5'Flank (SNP) | VAF 25/76 reads (33%) | called by muse, mutect2, varscan2
- PSD3 | c.*5357C>A | 3'UTR (SNP) | VAF 5/31 reads (16%) | called by muse, mutect2, varscan2
- PSMB11 | c.*313C>A | 3'UTR (SNP) | VAF 41/56 reads (73%) | called by muse, mutect2, varscan2
- RAB8B | c.*1122T>C | 3'UTR (SNP) | VAF 47/104 reads (45%) | called by muse, mutect2, varscan2
- ROR1 | c.*357G>C | 3'UTR (SNP) | VAF 24/54 reads (44%) | called by muse, mutect2, varscan2
- RPL21 | c.130-35G>C | Intron (SNP) | VAF 5/43 reads (12%) | catalogued as rs950930768; called by muse, mutect2, varscan2
- RSF1 | c.734-947A>T | Intron (SNP) | VAF 56/104 reads (54%) | called by muse, mutect2, varscan2
- RUNX1T1 | c.88+13093A>T | Intron (SNP) | VAF 11/104 reads (11%) | called by muse, mutect2
- RXFP3 | c.*261G>A | 3'UTR (SNP) | VAF 34/91 reads (37%) | catalogued as rs1281035302; called by muse, mutect2, varscan2
- SEMA3A | c.*472A>C | 3'UTR (SNP) | VAF 36/104 reads (35%) | called by muse, mutect2, varscan2
- SLC17A8 | c.-110A>T | 5'UTR (SNP) | VAF 14/40 reads (35%) | called by muse, mutect2, varscan2
- SLC22A11 | c.*699C>A | 3'UTR (SNP) | VAF 37/96 reads (39%) | called by muse, mutect2, varscan2
- SLC45A4 | c.*1490A>T | 3'UTR (SNP) | VAF 15/82 reads (18%) | called by muse, mutect2, varscan2
- SMC1A | c.*5811G>A | 3'UTR (SNP) | VAF 54/115 reads (47%) | called by muse, mutect2, varscan2
- SON | c.6322-616T>G | Intron (SNP) | VAF 56/130 reads (43%) | called by muse, mutect2, varscan2
- STEAP4 | c.*1429C>T | 3'UTR (SNP) | VAF 8/45 reads (18%) | called by muse, mutect2, varscan2
- TGFB2 | c.*3038T>G | 3'UTR (SNP) | VAF 64/133 reads (48%) | called by muse, mutect2, varscan2
- TMEM9B | chr11:8964576 G>A | 5'Flank (SNP) | VAF 59/135 reads (44%) | called by muse, mutect2, varscan2
- TPD52 | c.*44C>T | 3'UTR (SNP) | VAF 33/75 reads (44%) | catalogued as rs779599352; called by muse, mutect2, varscan2
- TRDN | c.*1087C>G | 3'UTR (SNP) | VAF 13/91 reads (14%) | called by muse, mutect2, varscan2
- TRIM24 | c.364+170_364+186del | Intron (DEL) | VAF 18/38 reads (47%) | called by mutect2, varscan2
- TSPAN9 | c.*2541T>C | 3'UTR (SNP) | VAF 11/88 reads (13%) | called by muse, mutect2, varscan2
- UBE2E1 | c.152+24A>G | Intron (SNP) | VAF 58/119 reads (49%) | called by muse, mutect2, varscan2
- UBOX5 | c.*802T>A | 3'UTR (SNP) | VAF 18/29 reads (62%) | called by muse, mutect2, varscan2
- VCPKMT | c.*445T>C | 3'UTR (SNP) | VAF 13/22 reads (59%) | called by muse, mutect2, varscan2
- VIM | c.1009-88A>G | Intron (SNP) | VAF 22/72 reads (31%) | called by muse, mutect2, varscan2
- WNT8A | c.*289G>A | 3'UTR (SNP) | VAF 49/119 reads (41%) | called by muse, mutect2, varscan2
- WT1 | c.*661A>T | 3'UTR (SNP) | VAF 26/60 reads (43%) | called by muse, mutect2, varscan2
- WWC2 | c.-93C>T | 5'UTR (SNP) | VAF 4/13 reads (31%) | called by muse, mutect2
- ZIC1 | c.*2167A>C | 3'UTR (SNP) | VAF 25/71 reads (35%) | called by muse, mutect2, varscan2
- ZNF563 | c.*394G>T | 3'UTR (SNP) | VAF 12/24 reads (50%) | called by muse, mutect2, varscan2
